Somatic mutation profile of tumor specimen TARGET-10-PAPHDN-09A (aliquot TARGET-10-PAPHDN-09A-01D) from TARGET case TARGET-10-PAPHDN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,703 days).
Specimen TARGET-10-PAPHDN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6d0b5d1-b3fe-484e-8302-c8f0c437264c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHDN-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHDN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20f573f8-fa7e-48dc-8bfe-c9cda1fe2198

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs746085389; called by muse, mutect2, varscan2
- MOV10 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs760900913, COSV62491055; called by muse, mutect2, varscan2
- PRMT8 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs765952382; called by muse, mutect2, varscan2
- USP7 | c.3220C>T p.R1074W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs762752076; called by muse, mutect2, varscan2
- ALX1 | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CMC1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- DHX30 | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DOCK5 | c.5083G>A p.G1695R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- GNB2 | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPH1 | c.663+44G>A | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- VAMP1 | c.*301G>C | 3'UTR (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
